Somatic mutation profile of tumor specimen MBCProject_3947_T1_WES (aliquot MBCProject_3947_T1_WES_1) from CMI case MBCProject_3947, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_3947_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d1aa487-e111-4695-8651-4a9e458189d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3947_SALIVA (Saliva), aliquot MBCProject_3947_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dcdd9f4-2c2d-4cce-b81e-7be9ecc3b812

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs121964878, CM034217, COSV55730231; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 33/171 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA2 | c.7391C>T p.T2464M (on ENST00000614293; = p.T2434M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1173334061, COSV55799624; called by muse, mutect2, varscan2
- ABLIM2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs371815593; called by muse, mutect2, varscan2
- CEP85L | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100874448; called by muse, mutect2
- COLEC11 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775993317, COSV52600034; called by muse, mutect2, varscan2
- DDI1 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs145267261; called by muse, mutect2, varscan2
- IGF2R | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs754988891, COSV63631049; called by muse, mutect2, varscan2
- LTBP2 | c.3206C>T p.T1069M | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs779396017; called by muse, mutect2, varscan2
- NETO2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as rs375544263; called by muse, mutect2, varscan2
- PIK3R4 | c.1174T>C p.C392R | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1372959621; called by muse, mutect2, varscan2
- TRBV20-1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs201903499; called by muse, mutect2, varscan2
- TRIM45 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs144230559; called by muse, mutect2, varscan2
- ZBTB21 | c.435A>C p.Q145H | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as COSV60404526; called by muse, mutect2, varscan2
- ZMYM3 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV58738931; called by muse, mutect2, varscan2
- CXXC4 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- DNAH1 | c.492dup p.D165* | Frame Shift Ins (INS) | VAF 45/176 reads (26%) | called by mutect2, pindel, varscan2
- DNAI2 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THBS3 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDC20B | c.27G>C p.A9= | Silent (SNP) | VAF 28/212 reads (13%) | called by muse, mutect2, varscan2
- CHST8 | c.717C>T p.F239= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV52856339; called by muse, mutect2, varscan2
- DALRD3 | c.139C>T p.L47= | Silent (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- EMID1 | c.1275C>A p.G425= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV53324998; called by muse, mutect2, varscan2
- TMEM245 | c.2214C>T p.F738= | Silent (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- VSTM2B | c.594C>T p.G198= | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- ZMYND11 | c.1492C>T p.L498= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV59078646; called by muse, mutect2
- ZNF107 | c.1020C>T p.F340= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV100788438; called by muse, mutect2, varscan2
- MAP4K4 | c.180+6581dup | Intron (INS) | VAF 45/228 reads (20%) | called by mutect2, pindel, varscan2
